Gene-level copy-number profile of tumor specimen TCGA-29-1770-02A from TCGA case TCGA-29-1770, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 54.8 years (20,015 days).
Specimen TCGA-29-1770-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.dea4702d-8a1e-4b70-b463-1ead2345e265.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-29-1770-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 363 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: a second ASCAT2 file.
https://portal.gdc.cancer.gov/files/9869f850-b8ae-48c0-a5b5-4755dc92b072

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 539; copy number 1: 2,071; copy number 2: 22,251; copy number 3: 18,884; copy number 4: 11,438; copy number 5: 3,272; copy number 6: 1,139; copy number 7: 346; copy number 8: 315; copy number 10: 1; copy number 20: 4.

Homozygous deletions (total copy number 0; autosomes only): 19 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:8,750,430–8,807,051, 5 genes: RPL7P11, RPL7P7, Y_RNA, AL357552.1, AL357552.2.
- chr6:138,422,043–138,692,571, 1 gene (within-gene range 0–2): NHSL1.
- chr6:138,650,226–139,291,998, 13 genes: AL590617.1, AL590617.2, CCDC28A-AS1, CCDC28A, ECT2L, ACKR4P1, AL121834.1, REPS1, ABRACL, HECA, AL031772.1, AL158850.1, TXLNB.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5,077 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:105,587,575–105,618,991, 1 gene, copy number 6: LINC01676.
- chr1:224,107,282–246,507,312, 490 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr3:99,638,475–190,892,429, 1,524 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr4:75,556,048–75,724,589, 4 genes, copy number 5 (within-gene range 2–5): ODAPH, CDKL2, G3BP2, Y_RNA.
- chr4:127,532,828–154,753,120, 369 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr4:180,573,464–180,574,027, 1 gene, copy number 10: NDUFB5P1.
- chr4:181,237,358–190,092,279, 181 genes, copy number 5–6 (broad region; genes not listed).
- chr5:58,198–34,899,456, 532 genes, copy number 6–7 (broad region; genes not listed).
- chr6:32,517,353–32,589,848, 4 genes, copy number 20: HLA-DRB5, RNU1-61P, HLA-DRB6, HLA-DRB1.
- chr7:138,594,285–138,701,362, 1 gene, copy number 5 (within-gene range 3–5): SVOPL.
- chr7:138,645,671–159,233,377, 527 genes, copy number 5 (broad region; genes not listed).
- chr8:103,398,635–145,066,685, 609 genes, copy number 5–8 (broad region; genes not listed).
- chr13:94,960,771–106,155,490, 155 genes, copy number 5 (broad region; genes not listed).
- chr15:19,878,555–23,856,375, 176 genes, copy number 5 (broad region; genes not listed).
- chr15:31,923,438–32,173,018, 1 gene, copy number 6 (within-gene range 4–6): CHRNA7.
- chr15:32,175,247–33,194,714, 35 genes, copy number 6 (within-gene range 4–6): Y_RNA, AC068448.1, AC139426.3, RNU6-18P, AC139426.1, AC139426.2, AC139426.4, DNM1P31, GOLGA8K, RN7SL185P, AC135983.1, ULK4P1, U8, DNM1P32, GOLGA8O, RN7SL539P, AC135983.5, AC135983.4, AC135983.3, AC135983.2, LINC02256, AC123768.3, AC123768.2, GOLGA8N, RN7SL286P, AC123768.1, ARHGAP11A, AC123768.4, SCG5, SCG5-AS1, AC090877.2, GREM1, FMN1, AC090877.1, AC018515.1.
- chr19:19,757,366–23,480,468, 181 genes, copy number 5 (broad region; genes not listed).
- chr19:36,378,028–37,906,677, 64 genes, copy number 5 (broad region; genes not listed).
- chr19:37,963,853–37,964,790, 1 gene, copy number 5: AC008395.1.
- chr19:52,012,765–53,308,644, 74 genes, copy number 5 (broad region; genes not listed).
- chr20:53,255,979–61,940,617, 147 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,984. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
